Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A3ZX, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A3ZX-01A (Primary Tumor).

Patient: [REDACTED]

AP Surgical Pathology: Additional Info.

Surg Path

CLINICAL HISTORY:

Rule out malignancy of left breast. Palpable left breast mass within large axillary node. If invasive carcinoma, please obtain ER, PR, EGFR, HER2/Neu by immunohistochemistry; for all 2+ IHC results please do FISH analysis.

GROSS EXAMINATION:

A. "USNCB left breast, number of cores 4, 11:00 site 1", received in formalin is a 1 x 0.6 x 0.2 cm aggregate of yellow-tan fibrofatty tissue which is submitted entirely in a mesh bag in block A1.

B. "USNCB left breast, number of cores 4, axilla site 2", received in formalin is a 0.9 x 0.6 x 0.2 cm aggregate of yellow-tan fibrofatty tissue which is submitted entirely in a mesh bag in block B1.

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

ICD-O-3

adenocarcinoma, infiltrating
ductal and lobular 8522/3

Site: breast, NOS C50.9 7-2-12, 20

DIAGNOSIS:

A. "LEFT BREAST, 11:00, SITE ONE" (ULTRASOUND GUIDED NEEDLE CORE BIOPSY):

INVASIVE ADENOCARCINOMA OF THE BREAST.

HISTOLOGIC TYPE: DUCTAL, WITH LOBULAR FEATURES.

NOTTINGHAM COMBINED HISTOLOGIC GRADE: 3 OF 3.

TUBULE FORMATION SCORE: 3.

NUCLEAR PLEOMORPHISM SCORE: 3.

MITOTIC RATE SCORE: 2.

IN-SITU CARCINOMA: PRESENT.

TYPE OF IN-SITU CARCINOMA: SOLID.

NUCLEAR GRADE OF IN-SITU CARCINOMA: 3 OF 3.

ESTROGEN/PROGESTERONE RECEPTOR, HER2/NEU, AND EGFR ANALYSIS: PENDING.

PARAFFIN BLOCK NUMBER: A1.

RESULTS WILL BE ISSUED IN A SEPARATE REPORT FROM THE IMAGE CYTOMETRY LAB.

B. "LEFT BREAST, AXILLA, SITE TWO" (ULTRASOUND GUIDED NEEDLE CORE BIOPSY):

LYMPH NODE WITH METASTATIC DUCTAL ADENOCARCINOMA.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 1:

Please see

for results of supplementary

tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file e6fddc6d-cdbf-492a-9ce7-a6adf033dc74 (TCGA-B6-A3ZX.B3CFFF02-89AA-43AE-B19B-BEE6817AA997.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).